Somatic mutation profile of tumor specimen 0DSYEG from CCDI case PBCIJF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Oligoastrocytoma; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 10.5 years (3,852 days).
Specimen 0DSYEG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0235a9c2-4101-41c7-af71-f622cc2a7785.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSYE9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2784d733-1523-4414-8301-46f40e7f2bcf

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC96 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 31/479 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs776708081, COSV59508776; called by muse, mutect2
- ISLR | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
